Somatic mutation profile of tumor specimen TARGET-20-PARHKX-09A (aliquot TARGET-20-PARHKX-09A-01D) from TARGET case TARGET-20-PARHKX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.2 years (2,646 days).
Specimen TARGET-20-PARHKX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74dd9406-11e3-4e86-9d39-09aa56a80f8d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARHKX-14A (Bone Marrow Normal), aliquot TARGET-20-PARHKX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3e5d94d-9149-4436-9938-191d783767e6

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- WT1 | c.1338_1341dup p.F448Kfs*18 | Frame Shift Ins (INS) | VAF 16/187 reads (9%) | catalogued as COSV60070795; called by mutect2, pindel
- GSE1 | c.1394_1402delinsCA p.V465Afs*21 | Frame Shift Del (DEL) | VAF 31/126 reads (25%) | called by pindel, varscan2*
